FM case AD2399 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/b7b42d49-c2d8-4ddd-9017-5e477c85543d

Female, 57.4 years: Melanoma, NOS (ICD-O-3 8720/3) of the eye; metastasis biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Metastatic.
